Surgical pathology report (de-identified scan), TCGA case TCGA-PK-A5HB, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University Health Network, specimen TCGA-PK-A5HB-01A (Primary Tumor).

[page 1 of 2]
LABORATORY MEDICINE PRC

ICD-3
Carcinoma, adrenal cortical
8370/3
Site: (R) Adrenal Gland, Cortex
C74.0
9/11/13

Surgical Pathology Consultation Report

Patient Name:	[REDACTED]	Accession #:	[REDACTED]
MRN:	[REDACTED]	Collected:	
DOB:	[REDACTED]	Received:	
Gender:	M	Reported:	
HCN:	[REDACTED]		
Ordering MD:			
Copy To:			

Specimen(s) Received

1. Spleen: spleenule
2. left spleen
3. Left adrenal distal pancreas, left kidney

Diagnosis

1. No pathological diagnosis: Accessory spleen; resection specimen.
2. No pathological diagnosis: Spleen, splenectomy specimen.
3. Adrenal cortical carcinoma, 12cm, 448 grams: Adrenal
- No pathological diagnosis: Kidney
- No pathological diagnosis: Pancreas
- Nopathological diagnosis: Lymph nodes, 2
- Left adrenalectomy, nephrectomy, splenectomy, and distal pancreatectomy specimen.

Electronically verified by:

Clinical History

None given.

Gross Description

1. The specimen container labeled with the patient's name and as "spleenule" contains a round grey-blue accessory spleen that measures 1.8 x 1.7 x 1.2 cm. On section the specimen is tan and grossly unremarkable.
1A - specimen submitted in toto.
2. The specimen container labeled with the patient's name and as "left spleen" contains an intact blue-grey spleen that measures 13.0 x 10.0 x 5.0 cm. The serosal surface and the cut surface are unremarkable. No nodes are identified in the hilar region. A piece of normal tissue is stored frozen. Representative sections are submitted as follows:
2A-D - four representative sections.
3. The specimen container labeled with the patient's name and as "left adrenal distal pancreas, left kidney" contains a kidney adherent to a large adrenal mass and an adherent portion of pancreas. The specimen measures 14.5 x 19.0 x 12.0 cm. The kidney measures 11.5 x 6.5 x 6.0 cm and is grossly unremarkable. The pancreas measures 5.5 x 3.0 x 2.3

[page 2 of 2]
Surgical Pathology Consultation Report

cm and is grossly unremarkable. The adrenal mass measures 12.0 x 8.5 x 9.5 cm and weighs 448 grams. Its cut surface is tan, partly solid, partly friable, and lobulated with foci of hemorrhage. No obvious adrenal parenchyma is identified but small patches of bright orange-yellow are seen particularly in the capsular region. In the perirenal fat there are several nodes that range in size from 0.3 cm in diameter to 9.0 cm in diameter. A piece of adrenal tumor is stored frozen.

Sections are submitted as follows:

3A-3C - sections of margin of tumor with identifiable adrenal gland and adjacent kidney

3D-3G - tumor

3H - One section, one pole of kidney

3I - opposite pole of kidney

3J - mid section of kidney

3K - three sections of margins of blood vessel at the hilar region of kidney

3L - resection margin of another vessel at the hilar region of the kidney

3M - resection margin of another vessel

3N-3O - two representative sections of the pancreas

3P - one node bisected

3Q - one small node bisected

3R - one node bisected

3S-3U adrenal cortex with tumor

3V-3X peripheral part of tumor with capsule

3Y-3AB central part of tumor, probable necrotic

3AC-AD tumor with kidney

Microscopic Description

1. Splenic tissue

2. Splenic tissue

3. Adrenal

DOMINANT LESION: invasive adrenal tumor

SIZE: 12 cm maximum dimension

WEIGHT: 448 grams

ARCHITECTURE: solid and trabecular architecture

CYTOLOGY: clear and compact cells with marked nuclear pleomorphism and numerous mitoses; numerous multinucleated cells

DEGENERATION: extensive geographic necrosis and broad fibrous bands

ENCAPSULATION: thick capsule

CAPSULAR INVASION: full thickness invasion present

EXTRA-ADRENAL INVASION: tumor invades peri-adrenal fat

RESECTION MARGINS: not involved

LYMPHOVASCULAR INVOLVEMENT: not identified

OTHER ADRENAL PATHOLOGY: none identified

LYMPH NODES: two identified,

Kidney: no significant pathologic alterations; minimal glomerulosclerosis

Pancreas: no significant pathologic alterations; discrete focal inflammation and fibrosis.

HIP-A Discrepancy		✓
Unusual/Synchronous Primary Malignancy		✓

Source: NCI Genomic Data Commons file 3326ccdc-abde-46d8-9ae8-4bf90b1e3039 (TCGA-PK-A5HB.5C732114-DD55-41D6-84C1-9BEDB7DF4345.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).